Gene-level copy-number profile of tumor specimen TCGA-2Y-A9H9-01A from TCGA case TCGA-2Y-A9H9, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.3 years (25,670 days).
Specimen TCGA-2Y-A9H9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.3af53cb2-f1aa-4eab-96dc-8fbb98ba2566.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9H9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0243858d-91c9-464b-a6c5-8d0258ae4635

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 6,182; copy number 3: 2,376; copy number 4: 41,642; copy number 5: 2,290; copy number 6: 4,165; copy number 7: 2,008; copy number 8: 790; copy number 9: 129; copy number 10: 125; copy number 11: 39; copy number 14: 24; copy number 16: 20; copy number 69: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9H9-01A-21D-A38W-01): tumor purity 0.88, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 351 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,373,711–154,870,281, 89 genes, copy number 10 (broad region; genes not listed).
- chr1:160,215,715–161,470,523, 69 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr1:189,132,350–190,494,297, 10 genes, copy number 10: GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1.
- chr1:207,454,230–208,736,286, 24 genes, copy number 9: CR2, CR1, AL137789.1, CR1L, CD46P1, CDCA4P3, RNA5SP534, AL137789.2, CD46, CDCA4P4, MIR29B2CHG, MIR29C, MIR29B2, CD34, AL356275.1, LINC02767, PLXNA2, AL590138.1, AL606753.1, AL606753.2, LINC01735, LINC02769, RPS26P13, LINC01717.
- chr1:213,731,416–214,357,615, 9 genes, copy number 11: AC096639.1, PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1, LINC02775, SMYD2, AL929236.1.
- chr1:233,836,080–233,905,931, 3 genes, copy number 9: AL663058.1, AL663058.2, AL713868.1.
- chr7:91,311,368–91,515,427, 1 gene, copy number 9 (within-gene range 7–9): AC079760.2.
- chr7:91,380,778–92,110,673, 5 genes, copy number 9 (within-gene range 7–9): AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9.
- chr7:107,563,484–108,003,213, 17 genes, copy number 9: DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3.
- chr7:136,685,559–137,182,107, 1 gene, copy number 10 (within-gene range 7–10): AC009264.1.
- chr7:136,868,669–137,354,483, 8 genes, copy number 10: CHRM2, MIR490, KRT8P51, AC009517.1, PTN, SNORD81, AC078842.2, AC078842.1.
- chr7:137,513,859–137,513,933, 1 gene, copy number 10: AC090498.1.
- chr7:143,509,256–144,131,188, 30 genes, copy number 11 (within-gene range 6–11): OR10AC1, AC073264.1, PAICSP5, CTAGE15, RNU6-162P, AC073264.2, TCAF1P1, AC073264.3, TCAF2, TCAF2C, RNU6-267P, CTAGE6, AC099548.2, PAICSP6, AC099548.1, TCAF2P1, TCAF1, OR2F2, OR2F1, CAPZA1P5, OR2Q1P, SLC16A1P1, OR6B1, OR2A5, OR2A25, OR2A41P, OR2A12, OR2A2, OR2A15P, OR2A14.
- chr11:69,147,228–69,704,022, 14 genes, copy number 69 (within-gene range 68–69): AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19.
- chr12:68,552,995–68,850,686, 16 genes, copy number 10: RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr17:32,492,522–32,877,177, 1 gene, copy number 14 (within-gene range 8–14): MYO1D.
- chr17:32,627,739–34,859,046, 43 genes, copy number 14–16: AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3, ASIC2, AC003687.1, AC008133.2, AC008133.1, AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1.
- chr17:66,638,271–67,056,797, 10 genes, copy number 9: RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
